FM case AD1769 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/9bdf16fa-3b8a-4a7d-9fb8-88af09c23e12

Female, 63.3 years: Clear cell adenocarcinoma, NOS (ICD-O-3 8310/3) of the uterus; metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
